Somatic mutation profile of tumor specimen MMRF_1391_1_BM_CD138pos (aliquot MMRF_1391_1_BM_CD138pos_T1_KAS5U_L00664) from MMRF case MMRF_1391, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.4 years (23,871 days).
Specimen MMRF_1391_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c46f7b5a-070e-4dae-96e3-10ad56e4ab9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1391_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1391_1_PB_Whole_C2_KAS5U_L00677; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a6cccbf-e392-4581-b226-89bc463e0b61

The open-access MAF lists 103 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 34, Silent 11, Intron 10, 3'Flank 7, 5'UTR 2, RNA 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*194G>A | 3'UTR (SNP) | VAF 6/63 reads (10%) | catalogued as rs28931614, CM940785, CM940786, CX090489, COSV53399372, COSV99602429; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.*676C>A | 3'UTR (SNP) | VAF 10/66 reads (15%) | catalogued as rs28933068, CM950474, CM950475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAN | c.4502C>A p.S1501Y | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV61355345; called by muse, mutect2
- ANKS1B | c.2905A>G p.T969A | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as rs1224773190; called by muse, mutect2, varscan2
- C5orf47 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs1363914509; called by muse, mutect2, varscan2
- DHRS12 | c.377C>T p.A126V (on ENST00000444610 / NM_001377930.1; = p.A77V on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1226768410; called by muse, mutect2
- EID2B | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58319347; called by muse, mutect2, varscan2
- ETV5 | c.1377C>G p.F459L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as rs1225932263; called by muse, mutect2, varscan2
- HMX3 | c.556A>C p.K186Q | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs1417620471; called by muse, mutect2, varscan2
- IGLV3-1 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 33/35 reads (94%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs61736463; called by muse, mutect2, varscan2
- MBD1 | c.808C>A p.R270S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV99495770; called by muse, mutect2, varscan2
- MCM10 | c.746C>T p.A249V (on ENST00000484800 / NM_182751.3; = p.A248V on NM_018518.5) | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as rs754237837; called by muse, mutect2, varscan2
- METAP1 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1265711553; called by muse, mutect2
- NALCN | c.1607G>A p.R536K | Missense Mutation (SNP) | VAF 34/35 reads (97%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs867018337, COSV51949153; called by muse, mutect2
- NUP88 | c.377T>C p.I126T | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs144721034; called by muse, mutect2, varscan2
- PLXNA4 | c.1549G>A p.G517S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs542202891, COSV58114201; called by muse, mutect2, varscan2
- RBM4 | c.875C>G p.A292G | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.525); catalogued as rs745344458, COSV100029716; called by muse, mutect2, varscan2
- SATB2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs142825652, COSV99612002; ClinVar: benign; called by muse, mutect2, varscan2
- TANC2 | c.3193C>T p.R1065C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs545352608, COSV67339920; called by muse, mutect2, varscan2
- TCN1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs560596044, COSV99953493; called by muse, mutect2, varscan2
- ZNF582 | c.441A>C p.E147D | Missense Mutation (SNP) | VAF 70/130 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV100018886; called by muse, mutect2, varscan2
- ADCY2 | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); called by muse, varscan2
- CCN3 | c.425C>G p.P142R | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CNTFR | c.85+2T>A p.X29_splice | Splice Site (SNP) | VAF 33/102 reads (32%) | called by muse, mutect2, varscan2
- DNAH8 | c.2474A>T p.H825L | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT16 | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GSX2 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- IL10 | c.517A>T p.T173S | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- IPO9 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL13 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2
- NMS | c.288C>A p.H96Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NPAS3 | c.2153C>T p.P718L (on ENST00000356141 / NM_001164749.2; = p.P686L on NM_022123.3) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PIK3C2G | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- PKD1L1 | c.4648A>T p.R1550W | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2
- PTPRM | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.14386A>T p.S4796C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- THBD | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ZNF211 | c.877T>A p.F293I (on ENST00000347302 / NM_198855.4; = p.F306I on NM_006385.5) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ASB10 | c.915C>T p.G305= (on ENST00000420175 / NM_001142459.2; = p.G290= on NM_080871.4) | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV51999183; called by muse, mutect2, varscan2
- CADPS2 | c.324C>A p.A108= | Silent (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- CDH18 | c.990T>C p.S330= | Silent (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2
- CHD2 | c.4425G>A p.R1475= | Silent (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2
- FARSB | c.1242C>G p.T414= | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as COSV56053246; called by muse, mutect2, varscan2
- FZD6 | c.1521T>C p.F507= | Silent (SNP) | VAF 70/132 reads (53%) | called by muse, mutect2, varscan2
- MYO15A | c.1737G>A p.T579= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1009942246; called by muse, mutect2, varscan2
- OBSCN | c.15324C>T p.A5108= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV52776748; called by muse, mutect2, varscan2
- OXCT2 | c.1479C>T p.D493= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs143322993; called by mutect2, varscan2
- SLCO4C1 | c.2142A>G p.E714= | Silent (SNP) | VAF 88/172 reads (51%) | catalogued as COSV100195443; called by muse, mutect2, varscan2
- ZNF518B | c.2274C>T p.S758= | Silent (SNP) | VAF 68/136 reads (50%) | catalogued as rs751589648; called by muse, mutect2, varscan2
- ACCS | c.556+89A>C | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.*1642G>C | 3'UTR (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- ADD2 | c.1593+48G>A | Intron (SNP) | VAF 39/74 reads (53%) | catalogued as rs782292701; called by muse, mutect2, varscan2
- ANKMY2 | c.*146C>A | 3'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- BCL2 | c.*3790A>G | 3'UTR (SNP) | VAF 24/40 reads (60%) | called by muse, mutect2, varscan2
- C1orf116 | c.*851T>G | 3'UTR (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- CDC37P2 | n.308T>C | RNA (SNP) | VAF 5/24 reads (21%) | called by mutect2, varscan2
- CRYBG2 | c.4038+17G>T | Intron (SNP) | VAF 27/52 reads (52%) | catalogued as rs1384728870; called by muse, mutect2, varscan2
- CSNK1G3 | chr5:123616083 ins T | 3'Flank (INS) | VAF 40/130 reads (31%) | catalogued as rs569181749; called by mutect2, varscan2
- DICER1 | c.*1111T>A | 3'UTR (SNP) | VAF 36/57 reads (63%) | called by muse, mutect2, varscan2
- EPHA5 | c.3008+163G>A | Intron (SNP) | VAF 30/50 reads (60%) | called by muse, mutect2, varscan2
- FOSL2 | c.*34G>T | 3'UTR (SNP) | VAF 13/93 reads (14%) | catalogued as rs776723974; called by muse, mutect2, varscan2
- GABRA1 | chr5:161897778 T>A | 3'Flank (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+20240T>C | Intron (SNP) | VAF 44/82 reads (54%) | called by muse, mutect2, varscan2
- GALC | c.*1220A>T | 3'UTR (SNP) | VAF 7/23 reads (30%) | catalogued as rs1376623818; called by muse, mutect2, varscan2
- GOLGB1 | c.*175G>A | 3'UTR (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- GPATCH11 | c.*2664T>A | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- GYG2 | c.*1352G>A | 3'UTR (SNP) | VAF 13/16 reads (81%) | catalogued as rs1328490803; called by muse, mutect2, varscan2
- HAO1 | c.*377A>G | 3'UTR (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2, varscan2
- HGF | c.*1540A>T | 3'UTR (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- HOXB3 | c.*11C>G | 3'UTR (SNP) | VAF 96/188 reads (51%) | catalogued as rs565883037, COSV100290616; called by muse, mutect2, varscan2
- HSD17B7 | c.448-125T>C | Intron (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- IRF4 | c.*281_*288del | 3'UTR (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- KIR2DL1 | chr19:54788259 A>G | 3'Flank (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- LBH | c.*147G>A | 3'UTR (SNP) | VAF 25/43 reads (58%) | called by muse, mutect2, varscan2
- LONRF2 | c.*3118G>T | 3'UTR (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- MAP4K5 | c.-23C>T | 5'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- MCC | c.*3942_*3945dup | 3'UTR (INS) | VAF 17/41 reads (41%) | called by mutect2, pindel, varscan2
- MED17 | c.417+1096C>T | Intron (SNP) | VAF 11/34 reads (32%) | catalogued as rs908697565; called by muse, mutect2, varscan2
- MIR655 | n.58T>A | RNA (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- MSC | c.*119C>T | 3'UTR (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2
- NRXN1 | c.*1618T>A | 3'UTR (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- OLFM3 | chr1:101803161 del T | 3'Flank (DEL) | VAF 24/47 reads (51%) | catalogued as rs954766976; called by mutect2, varscan2
- PBX2 | c.*1133A>C | 3'UTR (SNP) | VAF 40/158 reads (25%) | called by muse, mutect2, varscan2
- PIEZO2 | chr18:10670423 G>T | 3'Flank (SNP) | VAF 46/78 reads (59%) | called by muse, mutect2, varscan2
- PIK3IP1 | chr22:31292535 G>T | 5'Flank (SNP) | VAF 10/30 reads (33%) | called by muse, varscan2
- PLAG1 | c.*3069G>C | 3'UTR (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*2743G>A | 3'UTR (SNP) | VAF 45/83 reads (54%) | called by muse, mutect2, varscan2
- PSD | c.*335C>A | 3'UTR (SNP) | VAF 12/25 reads (48%) | catalogued as rs2281583; called by muse, varscan2
- RBM4 | c.412+582G>C | Intron (SNP) | VAF 23/35 reads (66%) | called by muse, mutect2, varscan2
- SHTN1 | c.*1101A>G | 3'UTR (SNP) | VAF 10/50 reads (20%) | catalogued as rs1174626991; called by muse, mutect2, varscan2
- SLC35E4 | chr22:30649213 C>T | 3'Flank (SNP) | VAF 28/28 reads (100%) | catalogued as rs946474072; called by muse, mutect2, varscan2
- SPOCK3 | c.*1517A>T | 3'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- STPG1 | c.*1408C>T | 3'UTR (SNP) | VAF 28/45 reads (62%) | called by muse, mutect2, varscan2
- TMPRSS4 | c.*3150A>T | 3'UTR (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- TRIM67 | chr1:231219624 G>T | 3'Flank (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- TRPC4 | c.*204T>G | 3'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- TTC16 | c.1117+188C>A | Intron (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- UBE2I | c.*238T>G | 3'UTR (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- USP22 | c.*1363G>C | 3'UTR (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- VIT | c.487+156A>G | Intron (SNP) | VAF 25/91 reads (27%) | catalogued as rs1172271253; called by muse, mutect2, varscan2
- ZBTB14 | c.*1080A>C | 3'UTR (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- ZBTB21 | c.*2349del | 3'UTR (DEL) | VAF 10/70 reads (14%) | called by mutect2, varscan2
- ZIC1 | c.-701C>T | 5'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
